HCMI case HCM-SANG-0528-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/4362ae25-19a3-4d5c-b608-af73414f1aa3

Demographics
Sex at birth: female; Days to birth: -28,306 days (77.5 years before the index date).

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.1; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Sites of involvement: Liver; Uicc pathologic m: M0; Uicc pathologic n: N1; Uicc pathologic stage: Stage IIB; Uicc pathologic t: T2; Uicc staging system edition: 7th.
   Pathology details: Peripancreatic lymph nodes positive: 1-3; Peripancreatic lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dexamethasone + Fluorouracil + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 684 days (1.9 years).

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Injected Insulin.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Alcohol intensity: Occasional Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample HCM-SANG-0528-C25-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Samples HCM-SANG-0528-C25-85A-01D-A80T-32, HCM-SANG-0528-C25-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
